Surgical pathology report (de-identified scan), TCGA case TCGA-97-7553, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - NYU, specimen TCGA-97-7553-01A (Primary Tumor).

[page 1 of 3]
SPECIMENS:

1. F/S LLL NODULE
2. LYMPH NODES LEVEL 9
3. LYMPH NODES LEVEL 6
4. LUNG, LEFT LOWER LOBE
5. LYMPH NODES LEVEL 5

DIAGNOSIS:

1. LUNG, LEFT LOWER LOBE, WEDGE RESECTION:

- ADENOCARCINOMA OF LUNG, MIXED TYPE, MODERATELY TO POORLY DIFFERENTIATED, MEASURING 2.5 CM (SEE SUMMARY)

2. LYMPH NODES, LEVEL IX, BIOPSY:

- FIVE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/5)

3. LYMPH NODES, LEVEL VI, BIOPSY:

- SIX LYMPH NODES, NEGATIVE FOR CARCINOMA (0/6)

4. LUNG, LEFT LOWER LOBE, LOBECTOMY:

- NO RESIDUAL CARCINOMA
- CONGESTION OF LUNG PARENCHYMA
- UNREMARKABLE BRONCHIAL AND VASCULAR MARGINS
- ELEVEN LYMPH NODES, NEGATIVE FOR CARCINOMA (0/11)

5. LYMPH NODES, LEVEL V, BIOPSY:

- SIX LYMPH NODES, NEGATIVE FOR CARCINOMA (0/6)

SUMMARY

Type: Adenocarcinoma

Histologic Type: Mixed type including acinar, bronchioloalveolar and solid subtypes with focal sarcomatoid pattern (slide 1E)

Location: Left lower lobe

Histologic Grade: Moderately to poorly differentiated

Nuclear grade: Intermediate to high

Surgical margins: Negative

Direct Extension of Tumor: Confined to lung parenchyma; pleura is uninvolved by the tumor.

Lymphovascular Invasion: Absent

Lymph nodes: 0/28

Pathologic Staging: Stage IA (pT1 N0 Mx)

[page 2 of 3]
Pathologist

CLINICAL HISTORY AND PRE-OPERATIVE DIAGNOSIS:

Left lower lobe nodule, lung mass

MACROSCOPIC DESCRIPTION:

The specimen is received fresh in five parts labeled with the patient's name.

1. Part one is labeled 'left lower lobe nodule'. It consists of a wedge of lung, measuring 7.5 x 2 x 0.9 cm, and weighing 8 grams. There is an ill-defined hemorrhagic, shaggy tumor, measuring 2.5 cm located approximately 0.2 cm from the stapled margin. The staple margin and pleura is inked in black. The representative section of the tumor is frozen. The specimen is entirely submitted in to nine cassettes.

2. Part two is labeled 'level #9 lymph nodes'. It consists of a few anthracotic lymph nodes ranging in greatest dimension from 0.2 to 0.8 cm. Submitted in toto.

3. Part three is labeled 'level# 6 lymph nodes'. It is received fresh and consists of a few anthracotic lymph nodes ranging in greatest dimension from 0.6 to 0.4 cm. Submitted in toto.

4. Part four is labeled 'left lower lobe'. It weighs 103 grams lobe of lung measuring 13 x 9 x 4 cm. There is a bronchial remnant identified measuring 0.9 x 2.5 cm in length and diameter, stapled. On the lateral side of the lobe there is an 8 cm partially stapled area, which is 3.5 cm from the bronchial resection margin. The pleural surface around the defect is inked black. Serial sectioning of the lung shows no discrete lesion with hemorrhagic lung parenchyma. There are multiple anthracotic peribronchial lymph nodes identified ranging in greatest dimension from 0.3 to 0.6 cm. Representative sections are submitted.

5. Part five is labeled 'level # 5 lymph nodes'. It consists of a few anthracotic lymph nodes ranging in greatest dimension from 0.2 to 0.7 cm. Submitted in toto.

SUMMARY OF SECTIONS:

1A frozen section of tumor

1B-1I remainder of tissue

2A-2B in toto

[page 3 of 3]
3A-3B in toto
4A shaved bronchial and vascular resection margin
4B-4F sampled stapled area
4G-4H lymph nodes
5A-5B in toto

INTRA - OPERATIVE CONSULTATION:

1. Lung, left lower lobe, wedge resection:
- Adenocarcinoma

Results were discussed with Dr. [REDACTED]

Intra-Operative Consultation #1 performed by
[REDACTED]

Final Diagnosis performed by
[REDACTED]

The electronic signature attests that the named Attending Pathologist has evaluated the specimen referred to in the signed section of the report and formulated the diagnosis therein.

This report may include one or more immunohistochemical stain results that use analyte specific reagents.

The tests were developed and their performance characteristics determined by [REDACTED]

They have not been cleared or approved by the US Food and Drug Administration.

The FDA has determined that such clearance or approval is not necessary.

Source: NCI Genomic Data Commons file 8c986fb8-5d80-4e48-8b9e-2958e79597fe (TCGA-97-7553.85EEDAD8-21BE-4B10-910B-5B71802AE52F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).